FM case AD16433 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Ductal and Lobular Neoplasms; Primary site: Breast.
https://portal.gdc.cancer.gov/cases/88ed49be-7995-479d-8603-3e6a56e3bc1b

Female, 61.2 years: Infiltrating duct carcinoma, NOS (ICD-O-3 8500/3) of the breast; primary biopsied or resected from the breast. Tumor nuclei on the sequenced sample's slide: 60% (pathologist estimate recorded by GDC). Sample type: Primary Tumor.
